Somatic mutation profile of tumor specimen TCGA-BP-5186-01A (aliquot TCGA-BP-5186-01A-01D-1429-08) from TCGA case TCGA-BP-5186, project TCGA-KIRC (Kidney Renal Clear Cell Carcinoma). Sex at birth: female; Vital status: Alive; Primary diagnosis: Clear cell adenocarcinoma, NOS; Tissue or organ of origin: Kidney, NOS; AJCC pathologic stage: Stage I; Tumor grade: G2; Age at diagnosis: 50.2 years (18,348 days).
Specimen TCGA-BP-5186-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 0520ebce-e354-4a16-af25-87b67b357da6.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-BP-5186-11A (Solid Tissue Normal), aliquot TCGA-BP-5186-11A-01D-1429-08; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/c1239249-f2e1-4b4c-bf44-eb0a5788eb40

The open-access MAF lists 36 somatic variants for this specimen: 27 protein-altering or splice-affecting, 6 silent, 3 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 21, Silent 6, Nonsense Mutation 2, Splice Site 1, Frame Shift Del 1, Frame Shift Ins 1, RNA 1, 5'UTR 1, 5'Flank 1, Nonstop Mutation 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- VHL | c.463_463+4del p.X155_splice | Splice Site (DEL) | VAF 34/170 reads (20%) | hotspot (GDC flag); called by mutect2, pindel, varscan2
- ABCB4 | c.300_301insCCTGC p.S101Pfs*5 | Frame Shift Ins (INS) | VAF 8/68 reads (12%) | catalogued as COSV99710601; called by mutect2, pindel
- ADAMTS9 | c.1964C>A p.A655D | Missense Mutation (SNP) | VAF 76/307 reads (25%) | SIFT deleterious (0); PolyPhen possibly damaging (0.641); catalogued as COSV55776790; called by muse, mutect2, varscan2
- ANKRA2 | c.809G>T p.S270I | Missense Mutation (SNP) | VAF 9/94 reads (10%) | SIFT tolerated (0.19); PolyPhen benign (0.273); catalogued as COSV57140609; called by muse, mutect2
- ATG4D | c.1403C>A p.S468Y | Missense Mutation (SNP) | VAF 29/115 reads (25%) | SIFT deleterious (0); PolyPhen possibly damaging (0.804); catalogued as COSV57263891; called by muse, mutect2, varscan2
- CLPTM1 | c.173G>A p.G58D | Missense Mutation (SNP) | VAF 20/76 reads (26%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.844); catalogued as COSV61611374; called by muse, mutect2, varscan2
- DACT1 | c.2048C>A p.A683D | Missense Mutation (SNP) | VAF 12/38 reads (32%) | SIFT tolerated (0.09); PolyPhen probably damaging (0.962); catalogued as rs1238948516, COSV60019802; called by muse, mutect2, varscan2
- ELP1 | c.2584C>T p.Q862* | Nonsense Mutation (SNP) | VAF 33/157 reads (21%) | catalogued as COSV65896643, COSV65898594; called by muse, mutect2, varscan2
- GRID2 | c.2788A>T p.T930S | Missense Mutation (SNP) | VAF 43/148 reads (29%) | SIFT tolerated, low confidence (0.55); PolyPhen possibly damaging (0.899); catalogued as COSV56181949; called by muse, mutect2, varscan2
- GRTP1 | c.272A>G p.N91S | Missense Mutation (SNP) | VAF 8/110 reads (7%) | SIFT tolerated (0.2); PolyPhen benign (0.088); catalogued as COSV58149022; called by muse, mutect2
- INPP5B | c.1864A>G p.M622V (on ENST00000373023; = p.M542V on NM_005540.3 and 3 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 32/100 reads (32%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.877); catalogued as rs779724529, COSV65959698; called by muse, mutect2, varscan2
- NMT2 | c.1407T>A p.F469L | Missense Mutation (SNP) | VAF 43/186 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV100975479, COSV65381673; called by muse, mutect2, varscan2
- NUP50 | c.940T>G p.S314A | Missense Mutation (SNP) | VAF 22/87 reads (25%) | SIFT tolerated (0.29); PolyPhen benign (0.001); catalogued as COSV61660796; called by muse, mutect2, varscan2
- PBRM1 | c.3605C>A p.T1202K (on ENST00000296302 / NM_001366071.2; = p.T1177K on NM_018313.5) | Missense Mutation (SNP) | VAF 34/94 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV56265433; called by muse, mutect2, varscan2
- PIWIL2 | c.1693G>A p.G565R | Missense Mutation (SNP) | VAF 32/139 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.926); catalogued as COSV63250182; called by muse, mutect2, varscan2
- PLEKHH2 | c.1964G>A p.R655Q | Missense Mutation (SNP) | VAF 31/94 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs200629095; called by muse, mutect2, varscan2
- PRG4 | c.3470T>A p.L1157* | Nonsense Mutation (SNP) | VAF 20/180 reads (11%) | catalogued as COSV63355084; called by muse, mutect2, varscan2
- RIN2 | c.946G>T p.G316W (on ENST00000255006 / NM_001242581.1; = p.G267W on NM_018993.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 11/82 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV54785184, COSV99657698; called by muse, mutect2, varscan2
- SLC10A3 | c.1267G>C p.V423L | Missense Mutation (SNP) | VAF 17/63 reads (27%) | SIFT deleterious (0.04); PolyPhen benign (0.4); catalogued as COSV54835794; called by muse, mutect2, varscan2
- SLC1A5 | c.817A>G p.I273V | Missense Mutation (SNP) | VAF 20/103 reads (19%) | SIFT tolerated (0.08); PolyPhen benign (0.122); catalogued as COSV69466571; called by muse, mutect2, varscan2
- SPARCL1 | c.1984C>G p.L662V | Missense Mutation (SNP) | VAF 35/166 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.949); catalogued as COSV56802670; called by muse, mutect2, varscan2
- ST14 | c.1336T>A p.S446T | Missense Mutation (SNP) | VAF 35/129 reads (27%) | SIFT deleterious (0.01); PolyPhen benign (0.231); catalogued as COSV53831923; called by muse, mutect2, varscan2
- USP51 | c.2135A>T p.*712Lext*7 | Nonstop Mutation (SNP) | VAF 30/140 reads (21%) | catalogued as COSV72351523; called by muse, mutect2, varscan2
- ZFP37 | c.94C>A p.L32M | Missense Mutation (SNP) | VAF 104/403 reads (26%) | SIFT tolerated (0.21); PolyPhen benign (0.146); catalogued as rs1301210932, COSV65286092; called by muse, mutect2, varscan2
- ZMYND8 | c.3070A>G p.K1024E (on ENST00000311275 / NM_001363741.2; = p.K998E on NM_012408.6 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 77/297 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as COSV53684100; called by muse, mutect2, varscan2
- ACACA | c.4593C>A p.S1531R | Missense Mutation (SNP) | VAF 15/120 reads (13%) | SIFT deleterious (0.03); PolyPhen benign (0.034); called by muse, mutect2, varscan2
- COL11A2 | c.590del p.D197Vfs*86 (on ENST00000341947 / NM_080680.3; = p.D197Vfs*78 on NM_080679.2) | Frame Shift Del (DEL) | VAF 39/169 reads (23%) | called by mutect2, pindel, varscan2
- CACNA1S | c.4380A>T p.T1460= | Silent (SNP) | VAF 21/106 reads (20%) | catalogued as COSV62937251, COSV62941197; called by muse, mutect2, varscan2
- CACNA1S | c.3927C>T p.F1309= | Silent (SNP) | VAF 9/185 reads (5%) | catalogued as COSV62935950, COSV62937261; called by muse, mutect2
- CSNK1A1L | c.747T>C p.C249= | Silent (SNP) | VAF 18/176 reads (10%) | catalogued as COSV65789427; called by muse, mutect2, varscan2
- FCGBP | c.2841C>G p.V947= | Silent (SNP) | VAF 16/79 reads (20%) | called by muse, varscan2
- KDM4D | c.1449T>A p.A483= | Silent (SNP) | VAF 17/93 reads (18%) | catalogued as COSV58633922; called by muse, mutect2, varscan2
- MICAL2 | c.4974T>G p.L1658= | Silent (SNP) | VAF 20/274 reads (7%) | catalogued as COSV56284647; called by muse, mutect2
- AP000769.5 | chr11:65498832 del TTC | 5'Flank (DEL) | VAF 53/224 reads (24%) | called by mutect2, pindel, varscan2
- SSPOP | n.4404C>G | RNA (SNP) | VAF 5/52 reads (10%) | catalogued as COSV50486753; called by muse, mutect2, varscan2
- TSPAN32 | c.-16G>C | 5'UTR (SNP) | VAF 7/21 reads (33%) | catalogued as COSV99478246; called by muse, mutect2, varscan2
